Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29D, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29D-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Previous melanoma. Now ? metastatic nodes and neck. Also past history SCC skin cancer. Excision of nodes R neck (posterior triangle).

MACROSCOPIC DESCRIPTION

"LYMPH NODE RIGHT NECK". Note: portion has been taken for Tumour Banking. A fatty nodular piece of tissue 35 x 20 x 6mm which on cut surface contains a dark tan appearance. The nodule measures 19mm in maximum extent. All of nodular area embedded in blocks A & B.

MICROSCOPIC REPORT

The sections show a well circumscribed subcutaneous deposit of malignant melanoma. the tumour is partially encapsulated but also extends into fat and small foci are seen surrounding skeletal muscle. While the deposit may represent an involved node, residual lymphoid tissue is not seen. The cells are epithelioid and spindled with a high mitotic rate. Some melanin pigment is noted. The tumour stains positively for HMB45, S100 and Melan A. There is no lymphovascular invasion. The lesion is fully excised, being 0.3mm from the nearest surgical resection margin.

SUMMARY

"LYMPH NODE RIGHT NECK" - metastatic malignant melanoma.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, neck CT.M.O

W
6/2/11

Printed:

Page 1 of 1

Source: NCI Genomic Data Commons file d4773ac5-fc2d-4821-8e34-e114e71da6cd (TCGA-EE-A29D.FA9448E8-537D-4200-90AE-7A67332E5DDB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).